Somatic mutation profile of tumor specimen TCGA-06-6698-01A (aliquot TCGA-06-6698-01A-11D-1845-08) from TCGA case TCGA-06-6698, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.6 years (19,591 days).
Specimen TCGA-06-6698-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa084e77-150b-43eb-b71e-bce4e16970c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6698-10A (Blood Derived Normal), aliquot TCGA-06-6698-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/690a5936-5f30-48b6-b9c9-6e192aa414d7

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 24, Silent 8, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5855G>A p.W1952* (on ENST00000358273 / NM_001042492.3; = p.W1931* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 56/86 reads (65%) | catalogued as rs1567615766, CM062912, COSV62222781; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.265-1G>A p.X89_splice | Splice Site (SNP) | VAF 18/128 reads (14%) | hotspot (GDC flag); catalogued as CS075220, COSV57298233, COSV57300956, COSV57333151; called by muse, mutect2, varscan2
- RB1 | c.951_954del p.S318Nfs*13 | Frame Shift Del (DEL) | VAF 65/101 reads (64%) | catalogued as rs1566194323; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 61/81 reads (75%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALPK2 | c.3878T>C p.I1293T | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV64497508; called by muse, mutect2, varscan2
- ARHGEF12 | c.4328C>T p.T1443I | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as COSV63107502; called by muse, mutect2
- AXDND1 | c.2227C>G p.R743G | Missense Mutation (SNP) | VAF 89/116 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs771074994, COSV62647551, COSV62648978; called by muse, mutect2, varscan2
- CARD11 | c.3137C>T p.A1046V | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs377327574, COSV67800574; called by muse, mutect2, varscan2
- CD209 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 22/543 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs1311874163, COSV52654281, COSV52655029; called by muse, mutect2
- CDH8 | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100184083, COSV54847158; called by muse, mutect2, varscan2
- CYP11B1 | c.1280G>C p.R427P | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960470, COSV52826167, COSV52830501; called by muse, mutect2, varscan2
- EFTUD2 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 102/122 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68184988; called by muse, mutect2, varscan2
- GRIN2A | c.2387T>A p.L796H | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58057782; called by muse, mutect2, varscan2
- HP1BP3 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56564853; called by muse, mutect2, varscan2
- IL4R | c.1304C>G p.P435R | Missense Mutation (SNP) | VAF 57/77 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV50178563; called by muse, mutect2, varscan2
- KAZN | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.959); catalogued as rs201963397, COSV60455765; called by muse, mutect2, varscan2
- MTA1 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782259901, COSV58760578; called by muse, mutect2, varscan2
- NHLRC3 | c.237+1G>A p.X79_splice | Splice Site (SNP) | VAF 7/56 reads (13%) | catalogued as COSV61489820; called by muse, mutect2, varscan2
- NUDT12 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as COSV50092969; called by muse, mutect2
- NXPH1 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68319990; called by muse, mutect2
- PCDHGA1 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.327); catalogued as COSV65299968; called by muse, mutect2, varscan2
- PIK3CB | c.3146T>G p.L1049R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV56690569; called by muse, mutect2, varscan2
- RBM47 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55942295, COSV55943860; called by muse, mutect2, varscan2
- RRP1B | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 184/228 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61480621; called by muse, mutect2, varscan2
- SEC16A | c.2395G>C p.E799Q | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV51541500; called by muse, mutect2, varscan2
- SERPINB7 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs765584752, COSV60533909; called by muse, mutect2, varscan2
- SMARCAL1 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 26/31 reads (84%) | catalogued as COSV61923899; called by muse, mutect2, varscan2
- TSC2 | c.4493G>A p.S1498N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs137854879, CM1415044, CM991216, COSV51926288; ClinVar: not provided; called by muse, mutect2, varscan2
- RBP3 | c.1268A>T p.Q423L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C1QL4 | c.615C>T p.D205= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as COSV57743262; called by muse, mutect2, varscan2
- C9orf64 | c.180C>T p.A60= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as COSV59032367; called by muse, mutect2, varscan2
- CSRNP1 | c.1659G>A p.L553= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as rs374512400; called by muse, mutect2, varscan2
- FYB1 | c.243G>A p.P81= | Silent (SNP) | VAF 35/49 reads (71%) | catalogued as rs370543019; called by muse, mutect2, varscan2
- IGFL1 | c.69C>T p.H23= | Silent (SNP) | VAF 14/219 reads (6%) | catalogued as rs758857747, COSV71443709; called by muse, mutect2
- KCNG2 | c.492C>T p.R164= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1232889961, COSV60270559; called by mutect2, varscan2
- LPO | c.1821C>T p.I607= | Silent (SNP) | VAF 47/84 reads (56%) | catalogued as rs769826400, COSV51858737; called by muse, mutect2, varscan2
- OR51F1 | c.795G>A p.L265= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV58580977; called by muse, mutect2, varscan2
